Surgical pathology report (de-identified scan), TCGA case TCGA-3G-AB14, project TCGA-THYM (Thymoma), tissue source site MD Anderson Cancer Center, specimen TCGA-3G-AB14-01A (Primary Tumor).

[page 1 of 3]
Accession:
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) THYMUS AND MEDIASTINAL FAT:
THYMOMA, WITH FOCAL CAPSULAR INVASION (SEE COMMENT)
Margins of resection free of tumor.

COMMENT:

Immunohistochemical studies done on tumor sections show positive staining for keratin 5/6 and PAX8 in the epithelial cells and positive staining for CD99 in the lymphoid component of the tumor. The immunohistochemical pattern supports the above diagnosis.

GROSS DESCRIPTION

(A) THYMUS AND MEDIASTINAL FAT – The specimen consists of one pale pink unoriented thymus (8.5 x 6.0 x 1.2 cm) and yellow-gray fibroadipose tissue (9.5 x 6.5 x 1.3 cm).

The external surface of the thymus is pink-red and smooth. The external surface of the thymus inked and serial sectioned. Two pale gray well-demarcated, firm nodules (1.8 x 1.5 x 1.4 cm, 1.5 x 1.3 x 1.2 cm) are identified. The cut surface of the nodules are pale pink and with focal friable possible necrotic area. A 0.1 cm of possible capsule is identified at the larger nodule of the specimen. Small portion of tumor and normal tissue is submitted for tumor bank. The nodules are entirely submitted.

The external surface and cut surface of the adipose tissue are unremarkable. The specimen is representatively submitted.

INK CODE: Blue – external surface of the thymus.

SECTION CODE: A1-A3, entirely submitted of the larger nodule with possible capsule; A4, entirely submitted of smaller nodule with friable cut surface; A5, representative sectioning of the adipose tissue; A6, representative sectioning of the uninvolved thymus.

CLINICAL HISTORY

Mediastinal mass.

SNOMED CODES

T-C8000; M-85800

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

ICD-O3
Thymoma type B2, malignant 8584/3
path
Thymoma NOS, malignant 8580/3
Site Thymus C879
206/5/14

[page 2 of 3]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

M

ADDENDUM

This modified report is being issued to report additional diagnostic information.

DIAGNOSIS

(A) THYMUS AND MEDIASTINAL FAT:

INVASIVE THYMOMA AND ATYPICAL THYMOMA (SEE COMMENT)
TWO TUMOR NODULES: 1.8 x 1.5 x 1.4 CM AND 1.5 x 1.3 x 1.2 CM
TUMOR EXTENDS TO THE INKED MARGIN

2/18/14 - Update - TSS has determined that type B2 was sent to BCR.

COMMENT

1/31/14 TSS cannot determine which piece/subtype was submitted for TCGA. DQ

Two tumor nodules are identified. The larger tumor nodule is predominantly encapsulated and is histologically compatible with atypical Thymoma or type B3 in WHO schema. The smaller tumor nodule is widely invasive into surrounding fibroadipose tissue and is histologically compatible with type B2 in WHO schema.

The slides were reviewed for interpretation.

has reviewed the case and concurs with the

Entire report and diagnosis completed by:

-----END OF REPORT-----

For TSS dx discrepancy form, TCGA tumor is thymoma, B2.

OK -

Diagnosis Discrepancy	☒ Subtype	☐

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on _____) : _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Thymoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	B2	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Histologic subtype was not done at initial pathologic diagnosis. Reviewing Pathologist has re-reviewed the case slide and provided the WHO subtype.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file cd2877e2-0eb5-45fd-a930-1964c6471650 (TCGA-3G-AB14.0B31AEFF-6AA2-4C90-B827-0EA47BE38B86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).